Somatic mutation profile of tumor specimen TCGA-43-6773-01A (aliquot TCGA-43-6773-01A-41D-1945-08) from TCGA case TCGA-43-6773, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 76.8 years (28,036 days).
Specimen TCGA-43-6773-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62361143-97cf-482b-9b25-f6e0f7fe19fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-6773-10A (Blood Derived Normal), aliquot TCGA-43-6773-10A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b718e6c7-5010-4b8a-ba02-f6730d36ddfe

The open-access MAF lists 61 somatic variants for this specimen: 46 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 13, Nonsense Mutation 3, Frame Shift Del 1, Frame Shift Ins 1, Intron 1, Splice Region 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.86A>G p.D29G | Missense Mutation (SNP) | VAF 6/66 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057519921, COSV67960034, COSV67960332, COSV67961305; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 5/34 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519992, CM103210, COSV52670202, COSV52732998, COSV52834506, COSV52887765; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP8B1 | c.3261+1G>C p.X1087_splice | Splice Site (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99377911; called by muse, mutect2, varscan2
- CASP2 | c.713A>G p.Y238C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1263766668, COSV100131295; called by muse, mutect2, varscan2
- CBX2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.475); catalogued as COSV99491027; called by muse, mutect2
- CDH7 | c.608C>G p.S203* | Nonsense Mutation (SNP) | VAF 8/92 reads (9%) | catalogued as COSV100543285, COSV59882200; called by muse, mutect2
- CFHR4 | c.1186G>C p.D396H (on ENST00000367416 / NM_001201551.2; = p.D150H on NM_006684.5) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99261426; called by muse, mutect2, varscan2
- CLCN7 | c.1212C>T p.I404= | Splice Region (SNP) | VAF 7/67 reads (10%) | catalogued as COSV99247657; called by muse, mutect2, varscan2
- DCAF4L2 | c.99G>T p.Q33H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV60482641; called by muse, mutect2, varscan2
- DHH | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99908945; called by muse, mutect2
- DHX40 | c.943A>C p.I315L | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV99233255; called by muse, mutect2
- DNAH2 | c.8416C>T p.R2806C | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as rs1195835191, COSV101209608; called by muse, mutect2
- DNAH2 | c.8417G>T p.R2806L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.076); catalogued as COSV101209609; called by muse, mutect2
- FKBP8 | c.577G>A p.A193T (on ENST00000222308 / NM_001308373.2; = p.A194T on NM_012181.5) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as COSV55892267; called by muse, mutect2, varscan2
- FSCN3 | c.665G>C p.G222A | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV99133966; called by muse, mutect2, varscan2
- GLYATL2 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99780556; called by muse, mutect2
- GRM8 | c.2113G>A p.V705I | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.044); catalogued as rs201999725; called by muse, mutect2, varscan2
- GTDC1 | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV99601955; called by muse, mutect2
- IKZF4 | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs745666717, COSV100009370; called by muse, mutect2
- KIAA0319 | c.2911G>A p.G971R | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV100985825; called by muse, mutect2
- LRRTM4 | c.1488G>A p.M496I | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV101297747, COSV69139116, COSV69143317; called by muse, mutect2, varscan2
- M1AP | c.1011G>T p.Q337H | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.667); catalogued as COSV99304532; called by muse, mutect2, varscan2
- MCM3 | c.2183C>T p.P728L (on ENST00000229854 / NM_001366374.2; = p.P718L on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/427 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.29); catalogued as rs757939863, COSV100009088; called by muse, mutect2
- MPO | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs773687000, COSV56564812; called by muse, mutect2, varscan2
- MPP4 | c.371G>C p.S124T | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.456); catalogued as COSV100207378; called by muse, mutect2, varscan2
- PACS1 | c.460C>A p.L154I | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57696836; called by muse, mutect2, varscan2
- PAOX | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.813); catalogued as COSV99530088; called by muse, mutect2
- PCBP1 | c.116T>G p.I39S | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV100340245, COSV104410191; called by muse, mutect2
- PGK2 | c.1247A>C p.N416T | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV100505717; called by muse, mutect2
- PLK4 | c.1115A>T p.Y372F | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV99584994; called by muse, varscan2
- RIC3 | c.1009G>C p.E337Q (on ENST00000309737 / NM_001206671.4; = p.E336Q on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.099); catalogued as COSV100112385; called by muse, mutect2
- SCN1A | c.5830A>T p.K1944* (on ENST00000303395 / NM_001202435.3; = p.K1933* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/97 reads (7%) | catalogued as rs1553519812, COSV100322248; called by muse, mutect2
- SCN1A | c.5182G>A p.G1728R (on ENST00000303395 / NM_001202435.3; = p.G1717R on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100322250; called by muse, mutect2, varscan2
- SCUBE1 | c.248A>G p.Y83C | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as rs1281496775, COSV99298702; called by muse, mutect2
- SLA | c.737C>T p.S246F (on ENST00000338087 / NM_001045556.3; = p.S286F on NM_006748.4) | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99603358; called by muse, mutect2, varscan2
- SLC18A1 | c.1208T>C p.I403T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as rs1421511032, COSV99368945; called by muse, mutect2, varscan2
- SMARCE1 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 26/184 reads (14%) | catalogued as COSV52861072, COSV99228504; called by muse, varscan2
- SMYD2 | c.581del p.L194Wfs*11 | Frame Shift Del (DEL) | VAF 25/151 reads (17%) | catalogued as rs1249055965; called by mutect2, pindel, varscan2
- SPTLC3 | c.578C>G p.T193R | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV100983305; called by muse, mutect2
- TRHDE | c.3072C>G p.H1024Q | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV53865799, COSV99672663; called by muse, mutect2
- TRPM6 | c.4501G>A p.D1501N | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV100667005; called by muse, mutect2
- VAV2 | c.1493A>G p.D498G (on ENST00000371850 / NM_001134398.2; = p.D488G on NM_003371.4) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100896219; called by muse, mutect2
- ZFHX3 | c.9473C>T p.T3158I | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV99214799; called by muse, mutect2, varscan2
- ZKSCAN4 | c.42G>T p.Q14H | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV101043575; called by muse, mutect2
- ZNF616 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV100348627; called by muse, mutect2
- ADCY8 | c.1474dup p.T492Nfs*14 | Frame Shift Ins (INS) | VAF 12/130 reads (9%) | called by mutect2, pindel
- ALDH5A1 | c.900G>C p.V300= | Silent (SNP) | VAF 15/205 reads (7%) | catalogued as COSV100708928, COSV62374220; called by muse, mutect2
- ARFIP2 | c.519G>A p.Q173= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99601688; called by muse, mutect2, varscan2
- BMP2K | c.3042T>A p.T1014= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV99785457; called by muse, mutect2
- FZD2 | c.729C>T p.F243= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as rs1278886384, COSV100190817; called by muse, mutect2
- GPR101 | c.108C>T p.T36= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV99981635; called by muse, mutect2, varscan2
- KDM1B | c.2109C>T p.P703= (on ENST00000449850; = p.P470= on NM_153042.4) | Silent (SNP) | VAF 20/191 reads (10%) | catalogued as rs376863878; called by muse, mutect2
- MCRS1 | c.333A>C p.P111= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as rs1565792867, COSV100657438; called by muse, mutect2
- OR2G3 | c.171C>T p.T57= | Silent (SNP) | VAF 44/298 reads (15%) | catalogued as rs146190470, COSV100180791; called by muse, mutect2, varscan2
- OR51B6 | c.696G>A p.R232= | Silent (SNP) | VAF 20/136 reads (15%) | catalogued as COSV100972032, COSV66512869; called by muse, mutect2, varscan2
- POLR1A | c.4362A>G p.E1454= | Silent (SNP) | VAF 7/123 reads (6%) | catalogued as rs1469251173, COSV99808470; called by muse, mutect2
- TNFAIP2 | c.991T>C p.L331= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs1226074794, COSV100281114; called by muse, mutect2, varscan2
- TSPYL2 | c.486G>A p.P162= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100212063, COSV100212427; called by muse, mutect2
- VNN2 | c.282C>T p.F94= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV58473834; called by mutect2, varscan2
- TMEM245 | c.2123+3990_2123+3994del | Intron (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- TRPV2 | chr17:16440206 A>G | 3'Flank (SNP) | VAF 15/113 reads (13%) | catalogued as rs781455040; called by muse, mutect2, varscan2
